MMRF case MMRF_2593 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/3e11c72c-f141-4abc-9f04-dd8012a601a9

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 65 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 65.8 years (24,037 days); ISS stage: I; Days to last known disease status: 638 days (1.7 years); Days to last follow up: 638 days (1.7 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 50 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 15 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 64 days; Days to treatment end: 64 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 90 days; Days to treatment end: 90 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 91 days; Days to treatment end: 91 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -2 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 123 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.486 mg/dL; Immunoglobulin G 6.93 g/L; Immunoglobulin A 0.81 g/L; Immunoglobulin M 0.61 g/L; Beta 2 Microglobulin 2.43 µg/mL; Lactate Dehydrogenase 7.88 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 211 ×10⁹/L; Creatinine 130 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.38 mmol/L; Albumin 39 g/L; Total Protein 6.2 g/dL; Glucose 5.39 mmol/L.
- Day 102 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.08 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.516 mg/dL; Immunoglobulin G 4.29 g/L; Immunoglobulin A 0.37 g/L; Immunoglobulin M 0.44 g/L; Beta 2 Microglobulin 1.94 µg/mL; Lactate Dehydrogenase 7.73 µkat/L; Hemoglobin 6.01 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 4.52 ×10⁹/L; Platelets 26 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.33 mmol/L; Albumin 33 g/L; Total Protein 5.3 g/dL; Glucose 4.57 mmol/L.
- Day 176 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.418 mg/dL; Immunoglobulin G 3.06 g/L; Immunoglobulin A 0.13 g/L; Immunoglobulin M 0.05 g/L; Beta 2 Microglobulin 1.9 µg/mL; Lactate Dehydrogenase 3.45 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 212 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.28 mmol/L; Albumin 42 g/L; Total Protein 5.8 g/dL; Glucose 5.28 mmol/L.
- Day 278 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.631 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.141 mg/dL; Immunoglobulin G 2.72 g/L; Immunoglobulin A 0.17 g/L; Immunoglobulin M 0.1 g/L; Lactate Dehydrogenase 3.02 µkat/L; Hemoglobin 9.18 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.33 mmol/L; Albumin 45 g/L; Total Protein 6 g/dL; Glucose 5.45 mmol/L.
- Day 369 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.94 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.196 mg/dL; Immunoglobulin G 2.77 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.17 g/L; Lactate Dehydrogenase 2.87 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 189 ×10⁹/L; Creatinine 118 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.33 mmol/L; Albumin 47 g/L; Total Protein 6.3 g/dL; Glucose 5.39 mmol/L.
- Day 454 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.536 mg/dL; Immunoglobulin G 3.31 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.34 g/L; Beta 2 Microglobulin 1.7 µg/mL; Lactate Dehydrogenase 3.03 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 223 ×10⁹/L; Creatinine 108 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.4 mmol/L; Albumin 46 g/L; Total Protein 6.4 g/dL; Glucose 5.72 mmol/L.
- Day 547 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.21 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.485 mg/dL; Immunoglobulin G 3.79 g/L; Immunoglobulin A 0.34 g/L; Immunoglobulin M 0.39 g/L; Lactate Dehydrogenase 5.98 µkat/L; Hemoglobin 8.8 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 220 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.33 mmol/L; Albumin 43 g/L; Total Protein 5.9 g/dL; Glucose 5.12 mmol/L.
- Day 638 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.974 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.487 mg/dL; Immunoglobulin G 4.34 g/L; Immunoglobulin A 0.41 g/L; Immunoglobulin M 0.41 g/L; Lactate Dehydrogenase 2.97 µkat/L; Hemoglobin 8.93 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 194 ×10⁹/L; Creatinine 125 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.38 mmol/L; Albumin 46 g/L; Total Protein 6.3 g/dL; Glucose 5.39 mmol/L.

Other clinical attributes
- Day -2: Weight: 79 kg; Height: 172 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2593_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -2 days.
- Sample MMRF_2593_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -2 days.
